TCGA case TCGA-AA-A024 — Colon Adenocarcinoma (TCGA-COAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Colon; Tissue source site: Indivumed. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d4e1472a-7b5f-46f4-acb7-b961f634e28e

Demographics
Sex at birth: male; Country of residence at enrollment: Germany; Age at index: 81 years; Vital status: Dead; Days to death: 1,188 days (3.3 years).

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C18.6; Tissue or organ of origin: Descending colon; Site of resection or biopsy: Descending colon; Classification of tumor: primary; Age at diagnosis: 81.3 years (29,708 days); Year of diagnosis: 2005; AJCC staging edition: 5th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,188 days (3.3 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 14.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Prior malignancy of the lung (histology not recorded by GDC).
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 1,188 days (3.3 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: day 61.

Molecular and laboratory tests
- CEA: 3.77 ng/mL.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-AA-A024-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 1,000 mg.
  Slide TCGA-AA-A024-01A-04-BS4: Section location: Bottom; Percent tumor cells: 14; Percent tumor nuclei: 50; Percent normal cells: 80; Percent necrosis: 1; Percent stromal cells: 5; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 1.
  Slide TCGA-AA-A024-01A-04-TS4: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 100; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 30; Percent monocyte infiltration: 5; Percent neutrophil infiltration: 0.
  Slide TCGA-AA-A024-01A-05-TS5: Section location: Top; Percent tumor cells: 5; Percent tumor nuclei: 3; Percent normal cells: 10; Percent necrosis: 1; Percent stromal cells: 82; Percent lymphocyte infiltration: 30; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
  Slide TCGA-AA-A024-01A-05-BS5: Section location: Bottom; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 100; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-AA-A024-01A-01-BS1: Section location: Bottom; Percent tumor cells: 60; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 1; Percent stromal cells: 39; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-AA-A024-01A-02-BS2: Section location: Bottom; Percent tumor cells: 88; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 10; Percent lymphocyte infiltration: 15; Percent monocyte infiltration: 3; Percent neutrophil infiltration: 1.
  Slide TCGA-AA-A024-01A-01-MS1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 28; Percent lymphocyte infiltration: 15; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 3.
- Sample TCGA-AA-A024-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-AA-A024-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Colon Mucinous Adenocarcinoma; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Lymph nodes examined: Yes; CEA level pretreatment: 3.77; KRAS gene analysis indicator: No; BRAF gene analysis indicator: No; History colon polyps: No; Mismatch rep proteins tested by IHC: No.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Remission/Response; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Other malignancy form: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Bronchus and Lung; Other malignancy histological type: malignant neoplasm of bronchus and lung: lower lobe.
- Other malignancy form, Surgery: Days from index date to other malignancy surgery: -3957.

GDC annotations on this case (curator notes; quoted as recorded):
- Prior malignancy: Patient had a prior malignancy of the bronchus and lung lower lobe. No radiation or systemic chemotherapy.
- Prior malignancy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,188 days; disease-specific survival: no event (censored), 1,188 days; disease-free interval: no event (censored), 1,188 days; progression-free interval: no event (censored), 1,188 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-AA-A024-01A-02D-A008-01): tumor purity 0.73, ploidy 2, whole-genome doublings 0.
